Gene-level copy-number profile of tumor specimen TCGA-66-2789-01A from TCGA case TCGA-66-2789, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 73.2 years (26,753 days).
Specimen TCGA-66-2789-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.595bdf80-14e5-4956-a0ea-89ac02102fe7.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-66-2789-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d271a51d-914e-42e4-a61c-92ad2448a8c3

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 71; copy number 1: 18,794; copy number 2: 31,264; copy number 3: 7,076; copy number 4: 1,189; copy number 5: 1,343; copy number 6: 26; copy number 14: 57.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-66-2789-01A-01D-0978-01): tumor purity 0.55, ploidy 1.97, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 59 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:50,088,919–50,672,048, 38 genes: RBM5, RBM5-AS1, SEMA3F-AS1, SEMA3F, AC104450.1, GNAT1, SLC38A3, GNAI2, MIR5787, U73169.1, U73166.1, SEMA3B-AS1, SEMA3B, MIR6872, LSMEM2, IFRD2, HYAL3, NAA80, HYAL1, HYAL2, TUSC2, RASSF1, RASSF1-AS1, ZMYND10-AS1, ZMYND10, NPRL2, CYB561D2, Z84492.2, TMEM115, CACNA2D2, Z84492.1, RNA5SP131, C3orf18, HEMK1, AC096920.1, CISH, MAPKAPK3, LINC02019.
- chr3:50,675,080–50,877,657, 5 genes: MIR4787, PPIAP69, AC126120.1, ZNF652P1, ST13P14.
- chr4:168,497,052–168,928,457, 1 gene (within-gene range 0–1): PALLD.
- chr4:168,647,896–169,010,275, 7 genes (within-gene range 0–1): PALLD-AS1, RNU6-1336P, RPL9P16, AC080188.1, AC080188.2, CBR4, RNU6-853P.
- chr4:183,762,115–184,073,039, 5 genes: AC108477.1, STOX2, AC074194.1, AC074194.2, AC107222.1.
- chr5:124,636,913–124,748,807, 3 genes: ZNF608, AC112196.1, AC113398.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,426 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:132,317,369–198,222,513, 1,141 genes, copy number 5 (broad region; genes not listed).
- chr8:38,099,471–40,353,133, 57 genes, copy number 14: AP006545.2, ASH2L, RNU6-988P, AC084024.1, STAR, AC084024.3, LSM1, RNU6-323P, BAG4, AC084024.2, AC084024.4, DDHD2, PLPP5, NSD3, AC087362.2, AC087362.1, AC087623.2, LETM2, FGFR1, AC087623.3, AC087623.1, RPS20P22, C8orf86, AC069120.1, RNF5P1, AC016813.1, TACC1, Y_RNA, AC067817.1, AC067817.2, PLEKHA2, AC108863.1, HTRA4, TM2D2, ADAM9, SNORD38D, ADAM32, RPL3P10, AC105185.1, ADAM5, ADAM3A, AC123767.1, ADAM18, ADAM2, AP005902.2, AP005902.1, IDO1, AC007991.3, AC007991.2, AC007991.4, IDO2, AC007991.1, AC087518.1, LINC02866, TCIM, AC022733.1, SIRLNT.
- chr16:35,528,367–35,912,516, 33 genes, copy number 5–6: AC018558.5, RARRES2P8, AGGF1P7, C2orf69P1, C1QL1P1, KIF18BP1, AC092325.1, AC106785.1, RNA5SP406, RNA5SP407, RNA5SP408, RNA5SP409, LINC02167, RNA5SP410, RNA5SP411, RNA5SP412, RNA5SP413, RNA5SP414, RNA5SP415, RNA5SP416, RNA5SP417, RNA5SP418, RNA5SP419, RNA5SP420, RNA5SP421, RNA5SP422, RNA5SP423, AC106785.2, HMGN2P41, VN1R70P, AC116553.1, AC116553.2, PPP1R1AP2.
- chr22:17,980,868–21,451,463, 195 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 16,425. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
